Somatic mutation profile of tumor specimen C3N-02327-01 (aliquot CPT0135380009) from CPTAC case C3N-02327, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 45.5 years (16,633 days).
Specimen C3N-02327-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ebead46e-a56a-4e2c-8ab0-55c87bce0fff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02327-71 (Blood Derived Normal), aliquot CPT0135500002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/579e5f6e-700d-4977-b380-2a2cf65ddb4f

The open-access MAF lists 77 somatic variants for this specimen: 51 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 23, Nonsense Mutation 10, Intron 2, Frame Shift Ins 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABRA | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 78/311 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.186); catalogued as rs780637593, COSV61731924; called by muse, mutect2, varscan2
- ACCSL | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 79/282 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as rs1252291215; called by muse, mutect2, varscan2
- ANKRD30B | c.2798G>A p.W933* | Nonsense Mutation (SNP) | VAF 56/456 reads (12%) | catalogued as rs764225698, COSV100271413, COSV100271643; called by muse, mutect2, varscan2
- ARSD | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 200/668 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.262); catalogued as rs1236144244; called by muse, mutect2, varscan2
- CCDC186 | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 109/419 reads (26%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs766549960; called by muse, mutect2, varscan2
- CHMP4C | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 92/289 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV99794212; called by muse, mutect2, varscan2
- COL9A2 | c.1802G>A p.G601E | Missense Mutation (SNP) | VAF 95/382 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1049863222; called by muse, mutect2, varscan2
- DNAH5 | c.9970G>A p.D3324N | Missense Mutation (SNP) | VAF 143/506 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54229332; called by muse, mutect2, varscan2
- EXTL2 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 78/323 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs920266256, COSV100921103; called by muse, mutect2, varscan2
- FMN2 | c.3755G>A p.S1252N | Missense Mutation (SNP) | VAF 300/666 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs1444245987; called by muse, mutect2, varscan2
- JMJD1C | c.4576A>G p.T1526A | Missense Mutation (SNP) | VAF 111/353 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1177783876; called by muse, mutect2, varscan2
- KRBOX4 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 163/574 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.328); catalogued as rs112665226, COSV99994361; called by muse, mutect2, varscan2
- NARS1 | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 64/332 reads (19%) | catalogued as rs752752210, COSV56878190; called by muse, mutect2, varscan2
- NCKAP5 | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 129/345 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV100490843; called by muse, mutect2, varscan2
- PBX4 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 80/289 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs750891971; called by muse, mutect2, varscan2
- PCDHA2 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 107/407 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV100973801, COSV65366979; called by muse, mutect2, varscan2
- PDGFC | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 118/444 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.551); catalogued as COSV56845171; called by muse, mutect2, varscan2
- PKD1 | c.8425C>T p.P2809S | Missense Mutation (SNP) | VAF 217/692 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV51919796; called by muse, mutect2, varscan2
- SERPINB2 | c.624G>A p.W208* | Nonsense Mutation (SNP) | VAF 103/295 reads (35%) | catalogued as rs1301911950, COSV55095083; called by muse, mutect2, varscan2
- TGM4 | c.688A>G p.I230V | Missense Mutation (SNP) | VAF 85/316 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1242405546; called by muse, mutect2
- TRIM77 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 81/301 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.087); catalogued as rs772259642, COSV68065929; called by muse, mutect2, varscan2
- WFDC8 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 101/389 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.828); catalogued as rs371165838; called by muse, mutect2, varscan2
- ABCC8 | c.901C>A p.L301I | Missense Mutation (SNP) | VAF 48/654 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.3); called by muse, mutect2
- ARMCX5-GPRASP2 | c.1538T>C p.I513T | Missense Mutation (SNP) | VAF 223/582 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CWC22 | c.1571C>T p.S524F | Missense Mutation (SNP) | VAF 89/297 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- DNAH6 | c.2975C>A p.T992N | Missense Mutation (SNP) | VAF 135/472 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- DNAJC1 | c.320G>A p.R107K | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DSC3 | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 103/296 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DZIP1 | c.2050G>A p.E684K (on ENST00000347108; = p.E665K on NM_014934.5) | Missense Mutation (SNP) | VAF 92/394 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- ENPP1 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FILIP1L | c.3029C>A p.S1010* (on ENST00000354552 / NM_182909.3; = p.S770* on NM_014890.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 60/370 reads (16%) | called by muse, varscan2
- FRMD4A | c.2614T>C p.S872P | Missense Mutation (SNP) | VAF 78/620 reads (13%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- GGT5 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 129/313 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- GPR158 | c.3076C>T p.Q1026* | Nonsense Mutation (SNP) | VAF 119/391 reads (30%) | called by muse, mutect2, varscan2
- LMTK3 | c.2435C>A p.A812E | Missense Mutation (SNP) | VAF 133/534 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRRK2 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 71/303 reads (23%) | called by muse, mutect2, varscan2
- MANEA | c.306T>G p.Y102* | Nonsense Mutation (SNP) | VAF 120/352 reads (34%) | called by muse, mutect2, varscan2
- MCMBP | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 108/393 reads (27%) | called by muse, mutect2, varscan2
- MMP20 | c.1414G>C p.V472L | Missense Mutation (SNP) | VAF 60/323 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- MUC21 | c.607_613del p.T203Vfs*238 | Frame Shift Del (DEL) | VAF 145/754 reads (19%) | called by mutect2, pindel, varscan2
- NXPE4 | c.1455A>T p.E485D (on ENST00000375478 / NM_001077639.2; = p.E201D on NM_017678.3) | Missense Mutation (SNP) | VAF 109/401 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- OR8J2 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 84/351 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.404); called by muse, mutect2
- PGR | c.2491C>T p.P831S | Missense Mutation (SNP) | VAF 68/267 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PODXL2 | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 75/477 reads (16%) | called by muse, mutect2, varscan2
- PSMD1 | c.1612G>C p.E538Q | Missense Mutation (SNP) | VAF 157/520 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- RRN3 | c.1755T>G p.S585R | Missense Mutation (SNP) | VAF 119/443 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- SHANK1 | c.1834G>A p.A612T | Missense Mutation (SNP) | VAF 16/418 reads (4%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.535); called by muse, mutect2
- TRPC4 | c.1620T>G p.Y540* | Nonsense Mutation (SNP) | VAF 100/363 reads (28%) | called by muse, mutect2, varscan2
- UBR4 | c.7700C>T p.P2567L | Missense Mutation (SNP) | VAF 111/403 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- VAMP7 | c.390A>C p.Q130H | Missense Mutation (SNP) | VAF 40/572 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.039); called by muse, mutect2
- VCAM1 | c.2086dup p.S696Ffs*3 | Frame Shift Ins (INS) | VAF 35/276 reads (13%) | called by mutect2, pindel, varscan2
- ACSL6 | c.111T>G p.A37= (on ENST00000379240; = p.A62= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 105/453 reads (23%) | called by muse, mutect2, varscan2
- ANAPC2 | c.1062C>T p.S354= | Silent (SNP) | VAF 95/308 reads (31%) | catalogued as rs774829272; called by muse, mutect2, varscan2
- AVPR1B | c.1218A>G p.S406= | Silent (SNP) | VAF 79/614 reads (13%) | called by muse, mutect2, varscan2
- CCR8 | c.261C>A p.S87= | Silent (SNP) | VAF 66/455 reads (15%) | called by muse, mutect2, varscan2
- FAM186A | c.4224G>A p.G1408= | Silent (SNP) | VAF 169/770 reads (22%) | called by muse, varscan2
- GGT5 | c.1380C>T p.P460= | Silent (SNP) | VAF 127/312 reads (41%) | called by muse, mutect2, varscan2
- HABP2 | c.612G>A p.G204= | Silent (SNP) | VAF 99/431 reads (23%) | catalogued as rs751178357, COSV63638167; called by muse, mutect2, varscan2
- IGF2R | c.5556C>T p.D1852= | Silent (SNP) | VAF 140/509 reads (28%) | catalogued as rs776404669; called by muse, mutect2, varscan2
- KANSL3 | c.1992C>T p.S664= (on ENST00000666923 / NM_001349262.2; = p.S638= on NM_001115016.3) | Silent (SNP) | VAF 73/269 reads (27%) | called by muse, mutect2, varscan2
- LAMA2 | c.6543C>T p.N2181= | Silent (SNP) | VAF 78/335 reads (23%) | called by muse, mutect2, varscan2
- LRRC17 | c.156C>T p.L52= | Silent (SNP) | VAF 213/504 reads (42%) | called by muse, mutect2, varscan2
- NCOA6 | c.3873C>T p.T1291= | Silent (SNP) | VAF 130/478 reads (27%) | called by muse, mutect2, varscan2
- NT5C3B | c.22C>T p.L8= | Silent (SNP) | VAF 129/441 reads (29%) | called by muse, mutect2, varscan2
- OAS3 | c.1689C>T p.P563= | Silent (SNP) | VAF 96/358 reads (27%) | catalogued as rs377049304; called by muse, mutect2
- PTGFR | c.546G>A p.S182= | Silent (SNP) | VAF 70/278 reads (25%) | catalogued as rs765817668, COSV66115222; called by muse, mutect2, varscan2
- RUBCNL | c.99G>A p.L33= | Silent (SNP) | VAF 115/452 reads (25%) | catalogued as rs1257146680; called by muse, mutect2, varscan2
- SLC6A2 | c.1599T>C p.V533= | Silent (SNP) | VAF 81/277 reads (29%) | called by muse, mutect2, varscan2
- SMG5 | c.2349C>T p.I783= | Silent (SNP) | VAF 123/566 reads (22%) | catalogued as COSV62433739, COSV62435559; called by muse, mutect2, varscan2
- TDRKH | c.1128C>T p.L376= | Silent (SNP) | VAF 123/610 reads (20%) | catalogued as rs781713188; called by muse, mutect2, varscan2
- TECPR1 | c.201C>T p.R67= | Silent (SNP) | VAF 208/476 reads (44%) | called by muse, mutect2, varscan2
- TOP2B | c.1438T>C p.L480= (on ENST00000264331 / NM_001330700.2; = p.L475= on NM_001068.3) | Silent (SNP) | VAF 90/294 reads (31%) | called by muse, mutect2, varscan2
- UIMC1 | c.1293A>G p.L431= | Silent (SNP) | VAF 93/309 reads (30%) | called by muse, mutect2, varscan2
- ZFAT | c.2991C>T p.A997= | Silent (SNP) | VAF 92/318 reads (29%) | called by muse, mutect2, varscan2
- ALAS2 | c.-15-1763G>A | Intron (SNP) | VAF 109/461 reads (24%) | catalogued as COSV100237843, COSV58192047; called by muse, mutect2, varscan2
- PIP5K1C | c.1920+1420C>T | Intron (SNP) | VAF 148/525 reads (28%) | called by muse, mutect2, varscan2
- SPATA8 | n.821G>A | RNA (SNP) | VAF 68/187 reads (36%) | catalogued as COSV60704560; called by muse, mutect2, varscan2
